Somatic mutation profile of tumor specimen TCGA-55-7907-01A (aliquot TCGA-55-7907-01A-11D-2167-08) from TCGA case TCGA-55-7907, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.2 years (28,201 days).
Specimen TCGA-55-7907-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e21f17a-1c29-4016-a61f-146b5d131f44.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7907-10A (Blood Derived Normal), aliquot TCGA-55-7907-10A-01D-2167-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f47a40cf-68d7-41db-94dd-d234416fc39f

The open-access MAF lists 1,263 somatic variants for this specimen: 974 protein-altering or splice-affecting, 257 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 824, Silent 257, Nonsense Mutation 84, Splice Site 28, Frame Shift Del 24, Intron 16, RNA 11, Splice Region 7, Frame Shift Ins 6, 5'UTR 2, 3'UTR 2, 3'Flank 1.

Variants (750 of 1,263; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GLI3 | c.3147C>G p.Y1049* | Nonsense Mutation (SNP) | VAF 7/46 reads (15%) | catalogued as rs779898173, COSV67893654; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 11/34 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 63/101 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AAK1 | c.2074G>C p.G692R | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.54); PolyPhen benign (0.103); catalogued as COSV68646118; called by muse, mutect2, varscan2
- ABCA9 | c.1964G>C p.R655P | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV60623082, COSV60629236; called by muse, mutect2, varscan2
- ABCB5 | c.1696G>C p.A566P (on ENST00000404938 / NM_001163941.2; = p.A121P on NM_178559.6) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51717940; called by muse, mutect2, varscan2
- ABCC11 | c.3348G>T p.K1116N | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV100750905, COSV62322702; called by muse, mutect2, varscan2
- ABCC2 | c.913G>C p.V305L | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV64971252; called by muse, mutect2, varscan2
- ABCD4 | c.446A>T p.D149V | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53993944; called by muse, mutect2, varscan2
- ABCG8 | c.743C>G p.A248G | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.556); catalogued as COSV55395817; called by muse, mutect2, varscan2
- ABL2 | c.1518G>T p.Q506H (on ENST00000502732 / NM_007314.4; = p.Q491H on NM_005158.5) | Missense Mutation (SNP) | VAF 57/97 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.081); catalogued as COSV61019400; called by muse, mutect2, varscan2
- AC131160.1 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as COSV100226150, COSV57701900; called by muse, mutect2, varscan2
- AC136428.1 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV101434938, COSV101434974; called by muse, mutect2, varscan2
- ACIN1 | c.2339G>T p.R780I | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.789); catalogued as COSV52980634; called by muse, mutect2, varscan2
- ACIN1 | c.2209G>A p.E737K | Missense Mutation (SNP) | VAF 42/132 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.535); catalogued as rs780842266, COSV52980662; called by muse, mutect2, varscan2
- ACIN1 | c.340C>T p.H114Y | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); catalogued as COSV52980674; called by muse, mutect2, varscan2
- ACOT13 | c.112G>A p.V38M | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.516); catalogued as COSV57765444; called by muse, mutect2, varscan2
- ACOT4 | c.706G>C p.D236H | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58336174; called by muse, mutect2, varscan2
- ACOT7 | c.965G>C p.R322P (on ENST00000377855 / NM_181864.3; = p.R312P on NM_007274.4) | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as COSV64115065; called by muse, mutect2, varscan2
- ACSM2A | c.262G>A p.E88K (on ENST00000219054; = p.E9K on NM_001308169.2) | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0.018); catalogued as COSV54581807; called by muse, mutect2, varscan2
- ACSM2A | c.356G>T p.W119L (on ENST00000219054; = p.W40L on NM_001308169.2) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); catalogued as COSV54588486; called by muse, mutect2, varscan2
- ACTN2 | c.1278G>T p.Q426H | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.06); PolyPhen benign (0.383); catalogued as COSV100857130, COSV63977545; called by muse, mutect2, varscan2
- ADAM19 | c.590G>T p.R197L | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.73); PolyPhen benign (0.127); catalogued as rs147812090, COSV57429128; called by muse, mutect2, varscan2
- ADAM21 | c.1022A>G p.H341R | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50804924; called by muse, mutect2, varscan2
- ADAM21 | c.1485del p.C496Vfs*50 | Frame Shift Del (DEL) | VAF 22/109 reads (20%) | catalogued as COSV99961626; called by mutect2, pindel, varscan2
- ADAMTS18 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.348); catalogued as COSV51421389; called by muse, mutect2, varscan2
- ADAMTS20 | c.4889G>T p.R1630L | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV67130572, COSV67132104, COSV67137399; called by muse, mutect2, varscan2
- ADAMTS20 | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 21/62 reads (34%) | catalogued as rs1297278572, COSV67137404; called by muse, mutect2, varscan2
- ADAMTSL1 | c.4615G>T p.A1539S | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.262); catalogued as COSV65876728, COSV65878684; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1386C>A p.C462* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV54463902; called by muse, mutect2, varscan2
- ADCY2 | c.575T>C p.L192P | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as COSV57893086; called by muse, mutect2, varscan2
- ADCY3 | c.1356G>T p.G452= | Splice Region (SNP) | VAF 47/130 reads (36%) | catalogued as COSV53171510; called by muse, mutect2, varscan2
- ADCY4 | c.1306C>G p.L436V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100156275, COSV60256713; called by muse, mutect2, varscan2
- ADGRB3 | c.768G>A p.M256I | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.45); PolyPhen benign (0.38); catalogued as COSV65414332; called by muse, mutect2, varscan2
- ADGRF1 | c.70-1G>C p.X24_splice | Splice Site (SNP) | VAF 8/42 reads (19%) | catalogued as COSV64800724; called by muse, mutect2, varscan2
- ADH7 | c.296-1G>T p.X99_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as COSV52922638; called by muse, mutect2, varscan2
- ADORA1 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55143815; called by muse, mutect2, varscan2
- AFAP1L1 | c.2053G>C p.D685H | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57047150; called by muse, mutect2, varscan2
- AGL | c.3616G>A p.E1206K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54057110; called by muse, mutect2, varscan2
- AIPL1 | c.901G>T p.V301L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51508405; called by muse, mutect2, varscan2
- AKAP1 | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61806738; called by muse, mutect2, varscan2
- AKAP12 | c.2590C>A p.Q864K | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.014); catalogued as COSV53580457; called by muse, mutect2, varscan2
- AL592490.1 | c.2762G>A p.R921K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV69425735, COSV69427467; called by muse, mutect2, varscan2
- ALDH1L1 | c.188G>T p.G63V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99857127; called by muse, mutect2, varscan2
- ALDH1L1 | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 36/122 reads (30%) | catalogued as COSV99857131; called by muse, mutect2, varscan2
- ALG13 | c.1767G>T p.M589I | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV52643759; called by muse, mutect2, varscan2
- ALPK1 | c.947G>A p.C316Y | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51583149, COSV51590336; called by muse, mutect2, varscan2
- ALS2 | c.2389G>T p.G797* | Nonsense Mutation (SNP) | VAF 11/67 reads (16%) | catalogued as COSV51891504; called by muse, mutect2, varscan2
- ANAPC1 | c.1358G>T p.R453L | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.966); catalogued as COSV61978702, COSV61980116; called by muse, mutect2, varscan2
- ANK1 | c.4885G>T p.D1629Y | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as rs772197636, COSV55892171; called by muse, mutect2, varscan2
- ANK1 | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55892185; called by muse, mutect2, varscan2
- ANKLE2 | c.2315G>C p.R772T | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as COSV61711122; called by muse, mutect2, varscan2
- ANO6 | c.924G>C p.M308I | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.798); catalogued as COSV57666442; called by muse, mutect2
- ANO7 | c.2075G>A p.W692* (on ENST00000274979; = p.W638* on NM_001370694.2) | Nonsense Mutation (SNP) | VAF 3/18 reads (17%) | catalogued as COSV51477570; called by muse, mutect2
- ANTXR1 | c.560A>T p.Q187L | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58012810, COSV58019808; called by muse, mutect2, varscan2
- ANXA11 | c.130A>T p.T44S | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV55417970; called by muse, mutect2, varscan2
- AP1G1 | c.92G>T p.C31F | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV55493990; called by mutect2, varscan2
- APOB | c.6112G>A p.D2038N | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.018); catalogued as COSV51948169; called by muse, mutect2, varscan2
- APOC1 | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); catalogued as COSV99377216; called by muse, mutect2, varscan2
- APOC1 | c.194+1G>T p.X65_splice | Splice Site (SNP) | VAF 19/94 reads (20%) | catalogued as COSV99377217; called by muse, mutect2, varscan2
- APP | c.1094del p.P365Lfs*46 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | catalogued as COSV100696342; called by mutect2, pindel
- ARAP2 | c.2701C>T p.Q901* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV58290905; called by muse, mutect2
- ARFGAP3 | c.1326G>C p.E442D | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as COSV54313877; called by muse, mutect2
- ARHGAP12 | c.839G>C p.R280P | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104410021, COSV60965584; called by muse, mutect2, varscan2
- ARHGAP25 | c.404C>A p.S135Y (on ENST00000409202 / NM_001007231.3; = p.S128Y on NM_014882.3) | Missense Mutation (SNP) | VAF 49/133 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54906890; called by muse, mutect2, varscan2
- ARHGEF1 | c.2613G>T p.Q871H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.191); catalogued as COSV100529073; called by muse, mutect2, varscan2
- ARHGEF11 | c.2841G>T p.R947S | Missense Mutation (SNP) | VAF 106/187 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV59357549; called by muse, mutect2, varscan2
- ARHGEF28 | c.1912A>T p.K638* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV55266474; called by muse, mutect2, varscan2
- ARMC9 | c.1656C>G p.I552M | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV63022968; called by muse, mutect2, varscan2
- ASPM | c.7177G>T p.A2393S | Missense Mutation (SNP) | VAF 98/280 reads (35%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as COSV54136370; called by muse, mutect2, varscan2
- ASTL | c.467G>C p.S156T | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.182); catalogued as COSV60905082, COSV60905490; called by muse, mutect2, varscan2
- ASTN1 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 45/86 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV56080674, COSV99921171; called by muse, mutect2, varscan2
- ATAD5 | c.2395C>G p.L799V | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV58977856; called by muse, mutect2, varscan2
- ATF7 | c.1360C>T p.R454C (on ENST00000548446 / NM_001366555.2; = p.R443C on NM_006856.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1326602415, COSV60645772; called by muse, mutect2, varscan2
- ATG16L1 | c.1196G>C p.R399P (on ENST00000392017 / NM_030803.7; = p.R380P on NM_017974.4) | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV61467427; called by muse, mutect2, varscan2
- ATP10D | c.3929C>G p.A1310G | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56711846; called by muse, mutect2
- ATP13A5 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222140268, COSV60873635; called by muse, mutect2, varscan2
- ATP6V0D2 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1321146856, COSV53416997; called by muse, mutect2, varscan2
- ATP6V1A | c.1761G>T p.K587N | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.477); catalogued as COSV99850006, COSV99850202; called by muse, mutect2, varscan2
- B3GALT2 | c.1003C>A p.R335S | Missense Mutation (SNP) | VAF 19/31 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV100813593, COSV66464464; called by muse, mutect2, varscan2
- BAHD1 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1365644659, COSV69084244; called by muse, mutect2, varscan2
- BAIAP2 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.027); catalogued as rs922220997, COSV58339325; called by muse, mutect2
- BBS7 | c.115G>T p.D39Y | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52658903; called by muse, mutect2, varscan2
- BCORL1 | c.4540G>T p.D1514Y | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54404177; called by muse, mutect2, varscan2
- BDH1 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 39/155 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.518); catalogued as COSV64019529; called by muse, mutect2, varscan2
- BICC1 | c.2389T>C p.S797P | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as rs1230679224, COSV54066145; called by muse, mutect2, varscan2
- BICD1 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55686047; called by muse, mutect2, varscan2
- BMERB1 | c.501C>A p.A167= | Splice Region (SNP) | VAF 24/97 reads (25%) | catalogued as COSV55511330; called by muse, mutect2, varscan2
- BMP1 | c.782G>C p.G261A | Missense Mutation (SNP) | VAF 36/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100109744; called by muse, mutect2, varscan2
- BOD1L1 | c.5172G>T p.E1724D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as rs1454065048, COSV99239736; called by muse, mutect2, varscan2
- BPIFA1 | c.125T>A p.L42* | Nonsense Mutation (SNP) | VAF 32/123 reads (26%) | catalogued as COSV62825048; called by muse, mutect2, varscan2
- BPIFB1 | c.691G>A p.E231K | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs546526666, COSV53608278; called by muse, mutect2, varscan2
- BPIFB4 | c.1460C>A p.P487Q | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64952059; called by muse, mutect2, varscan2
- BPTF | c.2043G>C p.Q681H | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100075234; called by muse, mutect2, varscan2
- BRCA2 | c.10207G>C p.E3403Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.367); catalogued as COSV58413773; called by muse, mutect2, varscan2
- BRINP2 | c.1556A>C p.Q519P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as COSV64179559; called by muse, mutect2, varscan2
- BTK | c.775G>T p.G259W | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100437316, COSV58119675; called by muse, mutect2, varscan2
- BTNL2 | c.1332G>T p.E444D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV66631744; called by muse, mutect2, varscan2
- BUD13 | c.1514G>T p.R505L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV52770120; called by muse, mutect2, varscan2
- C12orf4 | c.1642C>G p.L548V | Missense Mutation (SNP) | VAF 59/139 reads (42%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.998); catalogued as COSV54208969; called by muse, mutect2, varscan2
- C12orf40 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.565); catalogued as COSV61136518; called by muse, mutect2, varscan2
- C17orf97 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as COSV64077196; called by muse, mutect2, varscan2
- C1QB | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as COSV100152778; called by muse, mutect2, varscan2
- C1orf43 | c.596G>T p.R199L (on ENST00000368521 / NM_001297718.2; = p.R165L on NM_015449.4) | Missense Mutation (SNP) | VAF 15/97 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.176); catalogued as COSV62966726; called by muse, mutect2, varscan2
- C2CD3 | c.5452G>T p.A1818S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.053); catalogued as COSV58098579; called by muse, mutect2, varscan2
- C8A | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1235076031, COSV63485990; called by muse, mutect2, varscan2
- C8orf74 | c.397C>A p.Q133K | Missense Mutation (SNP) | VAF 88/315 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.194); catalogued as rs766237463, COSV58755227; called by muse, mutect2, varscan2
- C9orf131 | c.2227C>A p.R743S | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV56613578, COSV56615458; called by muse, mutect2, varscan2
- CA11 | c.257del p.P86Hfs*2 | Frame Shift Del (DEL) | VAF 21/56 reads (38%) | catalogued as COSV99320704; called by mutect2, pindel, varscan2
- CACNA1C | c.6547G>A p.E2183K (on ENST00000399634 / NM_001167625.1; = p.E2112K on NM_000719.7) | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV59758289; called by muse, mutect2, varscan2
- CALM1 | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV63663621; called by muse, mutect2, varscan2
- CAPZA2 | c.598G>T p.E200* | Nonsense Mutation (SNP) | VAF 26/93 reads (28%) | catalogued as rs1422357532, COSV100753941; called by muse, mutect2, varscan2
- CAPZA2 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100753942; called by muse, mutect2, varscan2
- CARD14 | c.1510G>T p.E504* | Nonsense Mutation (SNP) | VAF 4/26 reads (15%) | catalogued as COSV60126064; called by muse, mutect2
- CARMIL3 | c.3637C>G p.P1213A | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV53745985; called by muse, mutect2, varscan2
- CBLL2 | c.392A>T p.Q131L | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV60369959; called by muse, mutect2, varscan2
- CCBE1 | c.915G>A p.V305= | Splice Region (SNP) | VAF 22/95 reads (23%) | catalogued as rs1428840066, COSV67951235; called by muse, mutect2, varscan2
- CCDC15 | c.744G>T p.M248I | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV61084070; called by muse, mutect2, varscan2
- CCDC178 | c.2159G>T p.C720F (on ENST00000383096 / NM_001105528.3; = p.C682F on NM_198995.3) | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.811); catalogued as COSV55791861; called by muse, mutect2, varscan2
- CCDC30 | c.2020-1G>C p.X674_splice (on ENST00000340612; = p.X631_splice on NM_001080850.3) | Splice Site (SNP) | VAF 5/22 reads (23%) | catalogued as COSV59608751; called by muse, mutect2
- CCDC87 | c.2168G>T p.R723L | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.236); catalogued as COSV59578333, COSV59580196; called by muse, mutect2, varscan2
- CCDC89 | c.938G>T p.R313L | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as COSV100320928, COSV57034716; called by muse, mutect2, varscan2
- CCNB3 | c.4064A>T p.K1355M | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV52078351; called by muse, mutect2, varscan2
- CCND2 | c.216C>A p.C72* | Nonsense Mutation (SNP) | VAF 11/95 reads (12%) | catalogued as COSV54221503, COSV54225457; called by muse, mutect2, varscan2
- CCNT1 | c.922A>T p.S308C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV56065781; called by muse, mutect2, varscan2
- CCT8L2 | c.618C>A p.C206* | Nonsense Mutation (SNP) | VAF 18/98 reads (18%) | catalogued as COSV63462470; called by muse, mutect2, varscan2
- CD200R1 | c.82T>C p.C28R (on ENST00000471858 / NM_170780.3; = p.C51R on NM_138806.4) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs1240562962, COSV55602914; called by muse, mutect2, varscan2
- CD300E | c.355C>A p.P119T | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV60791468; called by muse, mutect2, varscan2
- CD300LB | c.283A>G p.R95G | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58726244; called by muse, mutect2, varscan2
- CD300LD | c.471C>A p.T157= | Splice Region (SNP) | VAF 15/69 reads (22%) | catalogued as COSV64710714; called by muse, mutect2, varscan2
- CD34 | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 52/265 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60414614; called by muse, mutect2, varscan2
- CD4 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV50594058, COSV50594373; called by muse, mutect2, varscan2
- CDC20B | c.1183C>A p.L395M | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99697068; called by muse, mutect2
- CDH12 | c.2292C>A p.D764E | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV66438147; called by muse, mutect2, varscan2
- CDH15 | c.151C>A p.P51T | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57026602; called by muse, mutect2, varscan2
- CDH4 | c.2323G>A p.D775N | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866907754, COSV64649038; called by muse, mutect2, varscan2
- CDK8 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV67422588; called by muse, mutect2, varscan2
- CDKL4 | c.736-1G>C p.X246_splice | Splice Site (SNP) | VAF 6/29 reads (21%) | catalogued as COSV66510781; called by muse, mutect2, varscan2
- CEACAM18 | c.795C>A p.Y265* | Nonsense Mutation (SNP) | VAF 91/146 reads (62%) | catalogued as COSV67283764; called by muse, mutect2, varscan2
- CEACAM6 | c.964G>T p.A322S | Missense Mutation (SNP) | VAF 25/146 reads (17%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as COSV52268855; called by muse, mutect2, varscan2
- CEP57 | c.725G>C p.R242T | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV57689993; called by muse, mutect2, varscan2
- CERS6 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 48/96 reads (50%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as rs773651193, COSV59834306; called by muse, mutect2, varscan2
- CES1 | c.536G>T p.S179I | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV62089233, COSV62089454; called by muse, mutect2, varscan2
- CFAP65 | c.2445G>C p.Q815H | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.328); catalogued as COSV58565374; called by muse, mutect2, varscan2
- CFAP74 | c.931G>T p.E311* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV54572554; called by muse, mutect2, varscan2
- CFH | c.2710G>A p.G904S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.321); catalogued as rs1212645085, COSV66411943; called by muse, mutect2, varscan2
- CFTR | c.289G>T p.V97L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as CD992496, COSV50084756; called by muse, mutect2, varscan2
- CHRM2 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57781690; called by muse, mutect2, varscan2
- CHRM2 | c.1248C>A p.C416* | Nonsense Mutation (SNP) | VAF 67/195 reads (34%) | catalogued as COSV57781697; called by muse, mutect2, varscan2
- CHRNA5 | c.1168A>G p.R390G | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.186); catalogued as COSV55140086; called by muse, mutect2, varscan2
- CHRND | c.478T>A p.F160I | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); catalogued as COSV51327908; called by muse, varscan2
- CILP | c.1029-1G>A p.X343_splice | Splice Site (SNP) | VAF 7/54 reads (13%) | catalogued as COSV56027090; called by muse, mutect2, varscan2
- CLDN20 | c.166T>A p.W56R | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV65697794; called by muse, mutect2, varscan2
- CLRN2 | c.80C>G p.A27G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55551528; called by muse, mutect2, varscan2
- CLRN2 | c.289C>T p.L97F | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV72512622; called by muse, mutect2, varscan2
- CLSTN2 | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71724014; called by muse, mutect2, varscan2
- CLSTN2 | c.2554G>T p.V852L | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.123); catalogued as COSV71724015; called by muse, mutect2, varscan2
- CMIP | c.1594G>T p.G532* (on ENST00000537098 / NM_198390.2; = p.G438* on NM_030629.3) | Nonsense Mutation (SNP) | VAF 13/53 reads (25%) | catalogued as COSV67699453, COSV67700010; called by muse, mutect2, varscan2
- CMPK1 | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.304); catalogued as COSV100898579; called by muse, mutect2, varscan2
- CNGA3 | c.875A>C p.E292A | Missense Mutation (SNP) | VAF 26/50 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55627262; called by muse, mutect2, varscan2
- CNGA4 | c.339G>T p.W113C | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.102); catalogued as COSV66006798; called by muse, mutect2, varscan2
- CNGB3 | c.886A>C p.T296P | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.116); catalogued as COSV60696136; called by muse, mutect2
- CNNM1 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs1320636081, COSV63203132; called by muse, mutect2
- CNTNAP2 | c.113C>A p.P38Q | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV100667840; called by muse, mutect2, varscan2
- CNTNAP2 | c.1849G>C p.D617H | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62168058, COSV62239373; called by muse, mutect2, varscan2
- COL11A1 | c.3731C>A p.S1244Y | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV62193401; called by muse, mutect2, varscan2
- COL14A1 | c.1576G>A p.V526I | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.024); catalogued as COSV52863312, COSV52864821; called by muse, mutect2, varscan2
- COL15A1 | c.2447C>A p.S816* | Nonsense Mutation (SNP) | VAF 32/84 reads (38%) | catalogued as COSV66648284; called by muse, mutect2, varscan2
- COL16A1 | c.3341G>T p.G1114V | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99594821; called by muse, mutect2
- COL19A1 | c.1519G>T p.G507C | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59583928; called by muse, mutect2, varscan2
- COL1A1 | c.551C>G p.S184C | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.371); catalogued as COSV56808549; called by muse, mutect2, varscan2
- COL22A1 | c.4025G>T p.G1342V | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100280111, COSV57325689; called by muse, mutect2, varscan2
- COL22A1 | c.2011C>A p.P671T | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.374); catalogued as COSV57354576; called by muse, mutect2, varscan2
- COL25A1 | c.421G>T p.G141* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV67656536; called by muse, mutect2, varscan2
- COL26A1 | c.404G>T p.R135L (on ENST00000313669 / NM_001278563.3; = p.R133L on NM_133457.4) | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV100561866, COSV58133909; called by muse, varscan2
- COL2A1 | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV61533210; called by muse, varscan2
- COL3A1 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58594819; called by muse, mutect2
- COL4A1 | c.4425C>A p.Y1475* | Nonsense Mutation (SNP) | VAF 79/313 reads (25%) | catalogued as COSV65426275, COSV65430377; called by muse, mutect2, varscan2
- COL4A2 | c.1517G>T p.G506V | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64624255; called by muse, mutect2, varscan2
- COL6A6 | c.6187C>T p.H2063Y | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.993); catalogued as rs1381587148, COSV62034313; called by muse, mutect2
- COMP | c.1717G>T p.G573C | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55876238; called by muse, mutect2, varscan2
- COP1 | c.403G>C p.V135L | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT tolerated (1); PolyPhen probably damaging (0.964); catalogued as COSV58173826; called by muse, mutect2, varscan2
- CPA4 | c.95G>A p.R32K | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.68); PolyPhen benign (0.011); catalogued as COSV55983511, COSV55984649; called by muse, mutect2, varscan2
- CPED1 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.138); catalogued as COSV60007111, COSV60010443; called by muse, mutect2, varscan2
- CPS1 | c.3961G>T p.A1321S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as COSV51821282; called by muse, mutect2, varscan2
- CRACD | c.2900C>T p.P967L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV51729143; called by muse, mutect2, varscan2
- CRB2 | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.113); catalogued as COSV100749697; called by muse, varscan2
- CRB2 | c.317A>C p.E106A | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV63505048; called by muse, varscan2
- CREB5 | c.455G>T p.R152L (on ENST00000357727 / NM_182898.4; = p.R145L on NM_004904.3) | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as COSV63217810, COSV63226189; called by muse, mutect2, varscan2
- CREBZF | c.218T>A p.V73E | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52630521; called by muse, mutect2, varscan2
- CRISP1 | c.240G>T p.K80N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT tolerated (0.71); PolyPhen benign (0.023); catalogued as COSV59994951; called by muse, mutect2, varscan2
- CRISP2 | c.707G>T p.C236F | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1390252325, COSV59256431; called by muse, mutect2, varscan2
- CRISP3 | c.399G>A p.M133I (on ENST00000371159 / NM_001368123.1; = p.M115I on NM_006061.4) | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV53822465; called by muse, mutect2
- CRISPLD1 | c.249G>A p.M83I | Missense Mutation (SNP) | VAF 25/183 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51546320, COSV51550707; called by muse, mutect2, varscan2
- CROT | c.1658del p.G553Efs*3 | Frame Shift Del (DEL) | VAF 38/160 reads (24%) | catalogued as COSV58974326, COSV58977121; called by mutect2, pindel, varscan2
- CRYBG2 | c.3538G>T p.G1180C | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100366777; called by muse, mutect2, varscan2
- CSMD1 | c.7309C>A p.H2437N (on ENST00000520002; = p.H2436N on NM_033225.6) | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59367861; called by muse, mutect2, varscan2
- CSMD3 | c.5934+1G>T p.X1978_splice (on ENST00000297405 / NM_001363185.1; = p.X1874_splice on NM_052900.3) | Splice Site (SNP) | VAF 9/88 reads (10%) | catalogued as COSV99838277; called by muse, mutect2
- CSMD3 | c.2380del p.A794Lfs*59 (on ENST00000297405 / NM_001363185.1; = p.A690Lfs*59 on NM_052900.3) | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as COSV52253128; called by mutect2, pindel, varscan2
- CSPG4 | c.2276T>C p.L759P | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV57900016; called by muse, mutect2, varscan2
- CTC1 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59854808; called by muse, mutect2, varscan2
- CTNND2 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58888242, COSV58889653; called by muse, mutect2, varscan2
- CTSG | c.649T>C p.Y217H | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.748); catalogued as COSV53536558; called by muse, mutect2, varscan2
- CUX2 | c.1633G>T p.G545W | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV55637150; called by muse, mutect2, varscan2
- CYLC2 | c.311C>A p.T104N | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.52); PolyPhen benign (0.33); catalogued as COSV66339040; called by muse, mutect2
- CYLD | c.2699G>T p.G900V | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61096916; called by muse, mutect2
- DAB1 | c.1573C>G p.P525A (on ENST00000371231; = p.P492A on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV64696840; called by muse, mutect2, varscan2
- DAB2 | c.462G>T p.Q154H | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57917908; called by muse, mutect2, varscan2
- DAB2IP | c.2152G>T p.G718W (on ENST00000408936; = p.G690W on NM_032552.3) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV52265962; called by muse, mutect2, varscan2
- DAPK1 | c.786G>C p.K262N | Missense Mutation (SNP) | VAF 55/146 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63790941; called by muse, mutect2, varscan2
- DCAF12L2 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63580916; called by muse, mutect2, varscan2
- DCAF17 | c.542G>C p.G181A | Missense Mutation (SNP) | VAF 6/95 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV59831008; called by muse, mutect2
- DCAF4L1 | c.482C>A p.A161E | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); catalogued as COSV60787183, COSV60788339; called by muse, mutect2, varscan2
- DCDC1 | c.2539G>A p.V847I | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1269078249, COSV60855007; called by muse, mutect2, varscan2
- DCDC1 | c.1744G>T p.A582S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.242); catalogued as COSV100663721; called by mutect2, varscan2
- DCDC2B | c.746C>A p.P249H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as COSV59085174; called by muse, mutect2, varscan2
- DDIAS | c.2145G>C p.E715D | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV61273023; called by muse, mutect2, varscan2
- DDIAS | c.2515G>T p.V839L | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV61273033; called by muse, mutect2
- DDO | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 38/181 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64470468; called by muse, mutect2, varscan2
- DENND2A | c.2828G>A p.R943H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs779960525, COSV52057134; called by muse, mutect2, varscan2
- DGKB | c.2021G>T p.W674L | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51811176; called by muse, mutect2, varscan2
- DHX38 | c.2795C>T p.A932V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51700227; called by muse, mutect2, varscan2
- DIAPH3 | c.3427C>T p.H1143Y | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.053); catalogued as rs1330263728, COSV64966609; called by muse, mutect2, varscan2
- DKK2 | c.76T>C p.S26P | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.137); catalogued as rs552274432, COSV53402046; called by muse, mutect2, varscan2
- DLG5 | c.4007G>T p.G1336V | Missense Mutation (SNP) | VAF 32/133 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as COSV64949393; called by muse, mutect2, varscan2
- DLG5 | c.743G>T p.R248M | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV64949397; called by muse, mutect2, varscan2
- DLGAP2 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV70102886; called by muse, mutect2, varscan2
- DLGAP2 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated (0.35); PolyPhen probably damaging (1); catalogued as rs371264718; called by muse, mutect2, varscan2
- DLGAP4 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as rs956282723, COSV59418698; called by mutect2, varscan2
- DMRT3 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV51902203, COSV51907479; called by muse, mutect2, varscan2
- DMXL2 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV51853713; called by muse, mutect2, varscan2
- DNAH8 | c.4306G>T p.E1436* | Nonsense Mutation (SNP) | VAF 23/72 reads (32%) | catalogued as COSV100546175, COSV59472484; called by muse, mutect2, varscan2
- DNAI2 | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV56758132, COSV56761840; called by muse, mutect2, varscan2
- DNAJB8 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV59878028, COSV59879377; called by muse, mutect2, varscan2
- DNER | c.463C>A p.P155T | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.356); catalogued as COSV59173784; called by muse, mutect2, varscan2
- DNMT3B | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52422016, COSV99142467; called by muse, mutect2, varscan2
- DPY19L4 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747865072, COSV68963634; called by muse, mutect2, varscan2
- DPYD | c.2600G>T p.R867L | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV64591144; called by muse, mutect2, varscan2
- DSEL | c.3213G>T p.L1071F | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.732); catalogued as COSV59489618, COSV59493874; called by muse, mutect2, varscan2
- DSG2 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55202003; called by muse, mutect2, varscan2
- DYSF | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV50386101, COSV50531125; called by muse, mutect2, varscan2
- DYSF | c.4548G>T p.E1516D | Missense Mutation (SNP) | VAF 134/345 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV50531302; called by muse, mutect2, varscan2
- DZIP1 | c.373C>A p.Q125K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61269009; called by muse, mutect2, varscan2
- DZIP3 | c.2705C>G p.S902* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as COSV64313425; called by muse, mutect2, varscan2
- EDNRA | c.1213A>T p.I405F | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as COSV60096261, COSV60099873; called by muse, mutect2, varscan2
- EFCAB3 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 23/131 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.987); catalogued as COSV59504066; called by muse, mutect2, varscan2
- EFR3A | c.2309A>C p.K770T | Missense Mutation (SNP) | VAF 31/56 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV54461293; called by muse, mutect2, varscan2
- EFR3A | c.2324A>T p.H775L | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.467); catalogued as COSV54461300; called by muse, varscan2
- EIF3C | c.956C>G p.A319G | Missense Mutation (SNP) | VAF 72/354 reads (20%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.926); catalogued as COSV59060882; called by muse, mutect2, varscan2
- EIF4G2 | c.245G>C p.R82T | Missense Mutation (SNP) | VAF 62/216 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV60598682; called by muse, mutect2, varscan2
- EIF4G3 | c.2078G>T p.G693V | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.677); catalogued as COSV51691179, COSV99943699; called by muse, mutect2, varscan2
- ELOVL2 | c.832G>A p.G278S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61156702; called by muse, mutect2, varscan2
- EMILIN2 | c.1558G>T p.G520W | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.781); catalogued as COSV54426543; called by muse, mutect2, varscan2
- EML4 | c.1354-1G>A p.X452_splice | Splice Site (SNP) | VAF 35/107 reads (33%) | catalogued as COSV59303629; called by muse, mutect2, varscan2
- EMSY | c.2374G>A p.E792K | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); catalogued as COSV58264775; called by muse, mutect2, varscan2
- EOMES | c.1037-2A>G p.X346_splice | Splice Site (SNP) | VAF 20/45 reads (44%) | catalogued as COSV55414838; called by muse, mutect2, varscan2
- EPB41L4B | c.841-1G>A p.X281_splice | Splice Site (SNP) | VAF 26/60 reads (43%) | catalogued as COSV65798377; called by muse, mutect2, varscan2
- EPHA8 | c.2602C>A p.H868N | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51288774; called by muse, mutect2, varscan2
- EPHA8 | c.2903+1G>T p.X968_splice | Splice Site (SNP) | VAF 12/36 reads (33%) | catalogued as COSV51288786; called by muse, mutect2
- EPHB6 | c.299C>A p.A100D | Missense Mutation (SNP) | VAF 71/258 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV67420387; called by muse, mutect2, varscan2
- EPPK1 | c.6231C>G p.D2077E | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV73262267; called by muse, mutect2
- ERBB4 | c.2413T>G p.L805V | Missense Mutation (SNP) | VAF 18/206 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV61513746; called by muse, mutect2
- ERBB4 | c.1623-1G>T p.X541_splice | Splice Site (SNP) | VAF 3/47 reads (6%) | catalogued as COSV99626626; called by muse, mutect2
- ERICH5 | c.816C>A p.D272E | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as COSV59316825; called by muse, mutect2, varscan2
- ESS2 | c.1406G>T p.R469L | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52818395; called by muse, mutect2, varscan2
- ESYT2 | c.2263A>T p.S755C (on ENST00000613624; = p.S679C on NM_020728.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV51755280; called by muse, mutect2, varscan2
- EVPL | c.5996G>A p.R1999H | Missense Mutation (SNP) | VAF 62/132 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs577682130, COSV100044724; called by muse, mutect2, varscan2
- EXOSC10 | c.1401G>C p.Q467H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as COSV58667409; called by muse, varscan2
- EYS | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.778); catalogued as COSV60997179; called by muse, mutect2, varscan2
- F13A1 | c.385G>T p.G129* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV53565136; called by muse, mutect2, varscan2
- F5 | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as CM032567, COSV63122982; called by muse, mutect2, varscan2
- FAF1 | c.638G>T p.G213V | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV100875780; called by muse, mutect2, varscan2
- FAF1 | c.637G>T p.G213* | Nonsense Mutation (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100875782; called by muse, mutect2, varscan2
- FAM135A | c.4012A>T p.T1338S (on ENST00000370479 / NM_001351599.1; = p.T1125S on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.866); catalogued as COSV52057366; called by muse, mutect2
- FAM135B | c.32C>A p.S11* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as COSV50521991, COSV50523965; called by muse, mutect2, varscan2
- FAM149A | c.1636A>C p.M546L (on ENST00000356371 / NM_001367768.2; = p.M255L on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57029742; called by muse, mutect2, varscan2
- FAM171A1 | c.362G>T p.R121L | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65313300, COSV65319010; called by muse, mutect2, varscan2
- FAM47A | c.1898C>A p.P633H | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT tolerated (0.54); PolyPhen benign (0.012); catalogued as COSV60499191; called by muse, mutect2, varscan2
- FAM83A | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV52685579, COSV52687447; called by muse, mutect2, varscan2
- FAM83H | c.661G>T p.G221W | Missense Mutation (SNP) | VAF 96/223 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66354458; called by muse, mutect2, varscan2
- FARP1 | c.2630-1G>T p.X877_splice | Splice Site (SNP) | VAF 6/53 reads (11%) | catalogued as COSV60345227; called by muse, mutect2, varscan2
- FAT3 | c.7679G>T p.R2560L | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53114210, COSV53145475; called by muse, mutect2, varscan2
- FAT3 | c.11401G>T p.E3801* | Nonsense Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV53118159, COSV53159525; called by muse, mutect2, varscan2
- FAT4 | c.13149G>T p.K4383N | Missense Mutation (SNP) | VAF 40/251 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.234); catalogued as COSV58702988; called by muse, varscan2
- FBN1 | c.7230C>A p.H2410Q | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.488); catalogued as COSV57327417; called by muse, mutect2, varscan2
- FBXL6 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57352990, COSV57353112; called by muse, mutect2, varscan2
- FBXL7 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs189208873; called by muse, mutect2, varscan2
- FBXO11 | c.1403A>T p.Y468F (on ENST00000403359 / NM_001190274.2; = p.Y384F on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.786); catalogued as COSV57024738; called by muse, mutect2, varscan2
- FBXO16 | c.158A>G p.Q53R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as COSV60777342; called by muse, mutect2, varscan2
- FBXO33 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.151); catalogued as COSV53235578; called by muse, mutect2, varscan2
- FBXO39 | c.275T>A p.L92Q | Missense Mutation (SNP) | VAF 118/180 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58622794; called by muse, mutect2, varscan2
- FBXO42 | c.1304G>A p.G435D | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.87); PolyPhen benign (0.053); catalogued as COSV65046648; called by muse, mutect2, varscan2
- FERMT3 | c.1486G>T p.A496S (on ENST00000279227 / NM_178443.3; = p.A492S on NM_031471.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.76); PolyPhen benign (0.197); catalogued as COSV54182682; called by muse, mutect2, varscan2
- FGD6 | c.2743G>T p.D915Y | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59696121; called by muse, mutect2, varscan2
- FGFR2 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as COSV60656332; called by muse, mutect2, varscan2
- FLG2 | c.5802C>G p.H1934Q | Missense Mutation (SNP) | VAF 114/236 reads (48%) | SIFT tolerated (0.72); PolyPhen benign (0.057); catalogued as COSV66171866; called by muse, mutect2, varscan2
- FMN2 | c.484G>T p.D162Y | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs747413802, COSV100146867, COSV60447753; called by muse, mutect2, varscan2
- FNDC3A | c.790G>T p.A264S (on ENST00000492622 / NM_001079673.2; = p.A208S on NM_014923.5) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.021); catalogued as COSV65696390; called by muse, mutect2, varscan2
- FNDC8 | c.314C>A p.P105H | Missense Mutation (SNP) | VAF 77/218 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV50102234, COSV50104935; called by muse, mutect2, varscan2
- FOCAD | c.385A>C p.T129P | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.244); catalogued as COSV58105936; called by muse, mutect2, varscan2
- FOS | c.1094A>T p.N365I | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57840215; called by muse, mutect2, varscan2
- FOXO1 | c.1595C>A p.S532Y | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.024); catalogued as COSV65426588, COSV65428095; called by muse, mutect2, varscan2
- FOXO3 | c.1679G>T p.S560I | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV100669977; called by mutect2, varscan2
- FRG2B | c.133A>T p.K45* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as COSV71043954; called by muse, mutect2, varscan2
- FRYL | c.8545T>C p.Y2849H | Missense Mutation (SNP) | VAF 31/180 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51958186; called by muse, mutect2, varscan2
- FSTL5 | c.2040C>A p.D680E | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV60221137; called by muse, mutect2, varscan2
- FSTL5 | c.852G>T p.R284S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV60221147; called by muse, mutect2
- FSTL5 | c.690C>A p.D230E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100054465, COSV60217671; called by muse, mutect2, varscan2
- FZD10 | c.992C>A p.T331K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57471977, COSV57475273; called by muse, mutect2, varscan2
- FZD7 | c.1687A>T p.R563* | Nonsense Mutation (SNP) | VAF 37/81 reads (46%) | catalogued as COSV53811274; called by muse, mutect2, varscan2
- G2E3 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52841390; called by muse, mutect2, varscan2
- GABRA4 | c.614C>A p.T205K | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.78); PolyPhen benign (0.059); catalogued as rs778574043, COSV51933457; called by muse, mutect2, varscan2
- GABRA5 | c.852A>T p.E284D | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); catalogued as COSV59484479; called by muse, mutect2, varscan2
- GABRG3 | c.167G>T p.R56I | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV61529715; called by muse, mutect2, varscan2
- GALK2 | c.358-1G>T p.X120_splice | Splice Site (SNP) | VAF 14/47 reads (30%) | catalogued as COSV59104393; called by muse, mutect2, varscan2
- GALNT13 | c.1530G>T p.E510D | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV67234255; called by muse, mutect2, varscan2
- GALNT17 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61183997; called by muse, mutect2, varscan2
- GAS2L2 | c.1946del p.G649Vfs*61 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | catalogued as rs1568099519; called by mutect2, pindel, varscan2
- GATA6 | c.47C>A p.A16D | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.42); catalogued as COSV52527257; called by muse, mutect2, varscan2
- GBA3 | c.611C>G p.S204C | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV72438461, COSV72438681; called by muse, varscan2
- GBF1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 37/129 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV64147363; called by muse, mutect2, varscan2
- GEMIN4 | c.1740G>C p.Q580H | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as COSV56747187; called by muse, mutect2, varscan2
- GIMAP1 | c.339C>A p.H113Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56189436; called by muse, mutect2, varscan2
- GLG1 | c.574G>C p.D192H | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.048); catalogued as rs749296601, COSV52668491; called by muse, mutect2, varscan2
- GLRA2 | c.577T>A p.F193I | Missense Mutation (SNP) | VAF 39/61 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV54346075; called by muse, mutect2, varscan2
- GLYCTK | c.779G>T p.S260I | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs745935723, COSV59793824; called by muse, mutect2, varscan2
- GMEB2 | c.911A>T p.Q304L | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as COSV56609059; called by muse, mutect2, varscan2
- GNL1 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.029); catalogued as COSV64835482; called by muse, mutect2, varscan2
- GP2 | c.335G>T p.R112L | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV56895251, COSV56896013; called by muse, mutect2, varscan2
- GPATCH8 | c.4414G>C p.A1472P | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); catalogued as COSV59197484; called by muse, mutect2, varscan2
- GPC5 | c.492C>A p.N164K | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.105); catalogued as COSV65621630; called by muse, mutect2, varscan2
- GPLD1 | c.1916C>G p.S639C | Missense Mutation (SNP) | VAF 53/139 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV57760176; called by muse, mutect2, varscan2
- GPR15 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.957); catalogued as rs904015698, COSV52520179, COSV52521236; called by muse, mutect2, varscan2
- GPR22 | c.1091C>A p.P364H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51761214; called by muse, mutect2, varscan2
- GPR4 | c.190C>G p.L64V | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59917945; called by muse, mutect2, varscan2
- GPR85 | c.968C>A p.A323D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as COSV51784990; called by muse, mutect2, varscan2
- GPRC5A | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.012); catalogued as rs1273874635, COSV50008512; called by muse, mutect2, varscan2
- GPRC5C | c.115G>C p.E39Q | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.143); catalogued as rs1333272541, COSV100702921; called by muse, mutect2, varscan2
- GRID2 | c.2257G>T p.D753Y | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56249814; called by muse, mutect2, varscan2
- GRIK4 | c.2453T>A p.V818E | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV70805927; called by muse, mutect2, varscan2
- GRIP1 | c.2207C>T p.A736V (on ENST00000359742 / NM_001379345.1; = p.A684V on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/93 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54037648; called by muse, mutect2, varscan2
- GRM5 | c.1464C>G p.D488E | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.967); catalogued as COSV59622629; called by muse, mutect2, varscan2
- GRN | c.1342A>G p.T448A | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV50008545; called by muse, mutect2, varscan2
- GSDMC | c.1012C>A p.Q338K | Missense Mutation (SNP) | VAF 50/93 reads (54%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.883); catalogued as COSV52698250; called by muse, mutect2, varscan2
- GSG1L | c.803C>A p.P268H (on ENST00000447459 / NM_001109763.2; = p.P113H on NM_144675.2) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV66581291; called by muse, mutect2, varscan2
- H2AC20 | c.271G>T p.D91Y | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV58612490, COSV58612937; called by muse, mutect2, varscan2
- H2BC9 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.812); catalogued as COSV55099027, COSV55099687, COSV99769055; called by muse, mutect2, varscan2
- HADHA | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 185/493 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66108399; called by muse, mutect2, varscan2
- HAGH | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 41/156 reads (26%) | catalogued as COSV66900419; called by muse, mutect2, varscan2
- HAO2 | c.290A>G p.Q97R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV58041621; called by muse, mutect2, varscan2
- HDAC9 | c.2107G>T p.G703C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67782639; called by muse, mutect2, varscan2
- HEATR5A | c.3124A>T p.N1042Y | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV66344445; called by muse, mutect2
- HEATR5B | c.6019C>G p.L2007V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV51857533; called by muse, mutect2, varscan2
- HECW1 | c.886C>A p.R296S | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67836832, COSV67837728; called by muse, mutect2, varscan2
- HECW1 | c.1574G>T p.R525L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.09); catalogued as rs1303699849, COSV67837732; called by muse, mutect2, varscan2
- HELB | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 30/157 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV56075628; called by muse, mutect2, varscan2
- HERC2 | c.13942G>T p.A4648S | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.219); catalogued as rs143209042; called by muse, mutect2, varscan2
- HIF3A | c.1456G>T p.D486Y (on ENST00000377670 / NM_152795.4; = p.D417Y on NM_022462.4) | Missense Mutation (SNP) | VAF 35/142 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52200429, COSV52203389; called by muse, mutect2, varscan2
- HIRA | c.911G>T p.S304I | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54278429; called by muse, mutect2, varscan2
- HIVEP3 | c.3085G>T p.V1029L | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV56021471; called by muse, mutect2, varscan2
- HKDC1 | c.2243A>C p.Y748S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373020719, COSV63578844; called by muse, mutect2, varscan2
- HMCN1 | c.4704A>T p.E1568D | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.994); catalogued as COSV54930872; called by muse, mutect2, varscan2
- HOXB5 | c.805C>G p.P269A | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53314016; called by muse, mutect2, varscan2
- HRNR | c.2384G>T p.G795V | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV64261722, COSV64262317; called by muse, mutect2, varscan2
- HSP90AA1 | c.1766C>A p.S589* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | catalogued as COSV53490868; called by muse, mutect2, varscan2
- HTR1A | c.828C>A p.C276* | Nonsense Mutation (SNP) | VAF 14/79 reads (18%) | catalogued as COSV60502455, COSV60502609; called by muse, mutect2, varscan2
- HTR2C | c.750C>A p.H250Q | Missense Mutation (SNP) | VAF 59/125 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV52203838, COSV52221497; called by muse, mutect2, varscan2
- HTR5A | c.616G>T p.V206L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.392); catalogued as COSV55286348; called by muse, mutect2, varscan2
- HTR7 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.26); catalogued as COSV53289917, COSV53291774; called by muse, mutect2, varscan2
- HYDIN | c.6620G>T p.C2207F | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59266986; called by muse, mutect2, varscan2
- IGDCC4 | c.3361T>C p.S1121P | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61538827; called by muse, mutect2, varscan2
- IGF2R | c.350G>C p.C117S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63631937; called by muse, mutect2, varscan2
- IGKV2D-29 | c.256A>G p.R86G | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101534384; called by muse, mutect2, varscan2
- IGSF10 | c.1450G>T p.E484* | Nonsense Mutation (SNP) | VAF 40/187 reads (21%) | catalogued as COSV56790402, COSV99194104; called by muse, mutect2, varscan2
- IGSF22 | c.872C>A p.T291N | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.666); catalogued as COSV60037637; called by muse, mutect2, varscan2
- IGSF9B | c.3475G>A p.G1159S | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); catalogued as COSV58065409, COSV58071551; called by muse, mutect2, varscan2
- IHH | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 32/46 reads (70%) | catalogued as COSV55393873; called by muse, mutect2, varscan2
- IKZF2 | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV59582680; called by muse, mutect2, varscan2
- IL16 | c.2902C>T p.P968S (on ENST00000302987 / NM_172217.5; = p.P267S on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs895192189, COSV57267268; called by muse, mutect2, varscan2
- IMMT | c.2047G>C p.E683Q | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.93); catalogued as COSV54478528; called by muse, mutect2, varscan2
- INA | c.1146G>T p.L382F | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481387692, COSV63976434; called by muse, mutect2, varscan2
- INHBA | c.737A>T p.Q246L | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV54224270; called by muse, mutect2, varscan2
- INSL4 | c.191C>A p.P64H | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.353); catalogued as COSV53329770; called by muse, mutect2
- INTS4 | c.370C>G p.H124D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV71091191; called by muse, mutect2, varscan2
- IQUB | c.2361G>T p.Q787H | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV61241788; called by muse, mutect2, varscan2
- IQUB | c.1759-1G>T p.X587_splice | Splice Site (SNP) | VAF 6/11 reads (55%) | catalogued as COSV100227200; called by muse, varscan2
- IRF4 | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 24/154 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.063); catalogued as COSV66705021, COSV66706054; called by muse, mutect2, varscan2
- IRF4 | c.667T>C p.C223R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.197); catalogued as COSV66706059; called by muse, mutect2, varscan2
- ITGA8 | c.338C>G p.T113S | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV65234270; called by muse, mutect2, varscan2
- ITGAL | c.1310A>T p.Q437L | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.009); catalogued as COSV63323722; called by muse, mutect2, varscan2
- ITGBL1 | c.1301G>T p.C434F | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66011111; called by muse, mutect2, varscan2
- ITPRID2 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV57475490; called by muse, mutect2, varscan2
- ITSN2 | c.1723+1G>C p.X575_splice | Splice Site (SNP) | VAF 5/43 reads (12%) | catalogued as COSV61952583; called by muse, mutect2
- JAML | c.175C>G p.L59V (on ENST00000356289 / NM_001098526.2; = p.L49V on NM_153206.3) | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.037); catalogued as COSV52629061; called by muse, mutect2, varscan2
- KAZALD1 | c.493C>A p.P165T | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.084); catalogued as COSV100930602; called by muse, mutect2, varscan2
- KCNA10 | c.777G>T p.K259N | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as COSV63905180; called by muse, mutect2, varscan2
- KCNA2 | c.589G>T p.G197C | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV60371138; called by muse, mutect2, varscan2
- KCNB1 | c.1562C>A p.P521H | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV65570348; called by muse, mutect2, varscan2
- KCNF1 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.556); catalogued as COSV54465117; called by muse, mutect2, varscan2
- KCNJ2 | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as COSV54661553, COSV54663946; called by muse, mutect2, varscan2
- KCNK16 | c.341T>A p.L114Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV64678959; called by muse, mutect2, varscan2
- KCNK3 | c.196G>T p.V66L | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.208); catalogued as COSV57194156; called by muse, mutect2
- KCNK5 | c.358C>G p.L120V | Missense Mutation (SNP) | VAF 38/133 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV63989162, COSV63989256; called by muse, mutect2, varscan2
- KCNMA1 | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54276922; called by muse, mutect2, varscan2
- KCNQ4 | c.429C>A p.F143L | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61275124; called by muse, mutect2, varscan2
- KCNS1 | c.1409T>A p.L470Q | Missense Mutation (SNP) | VAF 32/155 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.254); catalogued as COSV60260800; called by muse, mutect2, varscan2
- KCTD3 | c.2272G>T p.G758* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV52069638; called by muse, mutect2, varscan2
- KIDINS220 | c.5311C>G p.L1771V | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56757927; called by muse, mutect2, varscan2
- KIF14 | c.3952G>A p.V1318I | Missense Mutation (SNP) | VAF 85/259 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.037); catalogued as COSV66263480; called by muse, mutect2, varscan2
- KIF20B | c.3337C>G p.L1113V (on ENST00000371728 / NM_001284259.2; = p.L1073V on NM_016195.4) | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.202); catalogued as COSV53313825; called by muse, mutect2, varscan2
- KIF5A | c.2417C>A p.T806K | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.326); catalogued as COSV54057967; called by muse, mutect2, varscan2
- KIF6 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1380155439, COSV54690077; called by muse, mutect2, varscan2
- KLB | c.1330C>T p.L444F | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57304451; called by muse, mutect2, varscan2
- KLHL1 | c.814A>G p.T272A | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64780049; called by muse, mutect2, varscan2
- KLHL6 | c.225C>G p.I75M | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58068705; called by muse, mutect2, varscan2
- KMT2C | c.10622G>T p.G3541V | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV51486577; called by muse, mutect2, varscan2
- KRBA1 | c.2134G>T p.G712C | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.838); catalogued as COSV55443632; called by muse, varscan2
- KRT17 | c.431A>T p.K144M | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100245183; called by muse, varscan2
- KRT38 | c.808A>T p.N270Y | Missense Mutation (SNP) | VAF 44/278 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as COSV55847270; called by muse, mutect2, varscan2
- KRT5 | c.721G>C p.D241H | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV52862489, COSV52862838; called by muse, mutect2, varscan2
- L3MBTL1 | c.1025C>T p.P342L (on ENST00000418998 / NM_001377303.1; = p.P252L on NM_015478.7) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765448221, COSV64229415; called by muse, mutect2, varscan2
- LAMA1 | c.7079G>T p.R2360L | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.138); catalogued as COSV67539741, COSV67539971; called by muse, mutect2, varscan2
- LAMA2 | c.1898G>T p.S633I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV70353342, COSV70354414; called by muse, mutect2, varscan2
- LAMA2 | c.2882C>A p.A961E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV70353344; called by muse, mutect2, varscan2
- LAMB3 | c.3011C>T p.T1004I | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.044); catalogued as rs769833376, COSV50524890; called by muse, mutect2, varscan2
- LAT2 | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 59/239 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.127); catalogued as COSV51920997, COSV51922347; called by muse, mutect2, varscan2
- LATS1 | c.2360G>T p.G787V | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53586526, COSV53597892, COSV53603872; called by muse, mutect2, varscan2
- LCMT1 | c.298G>A p.G100S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66726809; called by muse, mutect2, varscan2
- LHX6 | c.696+1G>T p.X232_splice (on ENST00000373755 / NM_001242334.2; = p.X261_splice on NM_014368.5) | Splice Site (SNP) | VAF 9/26 reads (35%) | catalogued as COSV61345740; called by muse, mutect2, varscan2
- LMAN1L | c.1060-1G>T p.X354_splice | Splice Site (SNP) | VAF 12/84 reads (14%) | catalogued as COSV59003205; called by muse, mutect2, varscan2
- LMTK3 | c.739G>C p.G247R | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV54316217; called by muse, mutect2, varscan2
- LMX1A | c.931C>G p.P311A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.472); catalogued as rs186074862, COSV54226260; called by muse, mutect2, varscan2
- LPA | c.3215del p.G1072Efs*10 | Frame Shift Del (DEL) | VAF 65/376 reads (17%) | catalogued as COSV60311532; called by mutect2, pindel, varscan2
- LRP1B | c.11588G>C p.G3863A | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV67261177; called by muse, mutect2, varscan2
- LRP1B | c.10073A>C p.Q3358P | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.874); catalogued as COSV67261180; called by muse, mutect2, varscan2
- LRP1B | c.3197G>T p.C1066F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67196629, COSV67261184; called by muse, mutect2, varscan2
- LRRC18 | c.222C>A p.N74K | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as COSV53285393; called by muse, mutect2
- LRRC66 | c.778G>C p.D260H | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV58633823, COSV58636144; called by muse, mutect2, varscan2
- LRRC7 | c.3361G>T p.E1121* (on ENST00000651989 / NM_001370785.2; = p.E1088* on NM_001330635.3 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 17/54 reads (31%) | catalogued as COSV50568596; called by muse, mutect2, varscan2
- LSAMP | c.975G>T p.W325C | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV100371414; called by muse, mutect2, varscan2
- LTBP2 | c.2313G>T p.Q771H | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV56212487; called by muse, mutect2, varscan2
- MACF1 | c.3380G>T p.S1127I | Missense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV58394799; called by muse, mutect2, varscan2
- MADD | c.3226G>T p.G1076W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as COSV60628713, COSV60628745; called by muse, mutect2, varscan2
- MAGEB6 | c.1012C>A p.Q338K | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.194); catalogued as COSV66872868; called by muse, mutect2, varscan2
- MAGI2 | c.3105G>T p.Q1035H | Missense Mutation (SNP) | VAF 78/248 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as rs1366989008, COSV62689283; called by muse, mutect2, varscan2
- MAN1A1 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as COSV63782648, COSV63784126; called by muse, mutect2, varscan2
- MAP2K3 | c.604G>T p.G202C (on ENST00000342679 / NM_145109.3; = p.G173C on NM_002756.4) | Missense Mutation (SNP) | VAF 27/136 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57575641; called by muse, mutect2, varscan2
- MAP3K13 | c.2144A>G p.K715R | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs370957516; called by muse, mutect2, varscan2
- MAP4K1 | c.491C>A p.A164D | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV67712511; called by muse, mutect2
- MARK1 | c.2320C>T p.R774* | Nonsense Mutation (SNP) | VAF 37/76 reads (49%) | catalogued as COSV65070567; called by muse, mutect2, varscan2
- MBL2 | c.71C>A p.T24N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV64759217; called by muse, mutect2, varscan2
- MC3R | c.479A>T p.K160M | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV54764734; called by muse, mutect2, varscan2
- MC5R | c.615C>G p.Y205* | Nonsense Mutation (SNP) | VAF 148/629 reads (24%) | catalogued as COSV61255468; called by muse, mutect2, varscan2
- MCF2L | c.2642G>T p.G881V (on ENST00000375608; = p.G849V on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56180524; called by muse, mutect2, varscan2
- MCM7 | c.802G>A p.G268R | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57998382; called by muse, mutect2, varscan2
- MED12 | c.1569G>T p.M523I | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.23); PolyPhen benign (0.05); catalogued as COSV61352113; called by muse, mutect2, varscan2
- MED12 | c.2444G>T p.R815L | Missense Mutation (SNP) | VAF 59/107 reads (55%) | SIFT tolerated (0.37); PolyPhen benign (0.407); catalogued as CM156098, COSV61352124; called by muse, mutect2, varscan2
- METTL7B | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.46); PolyPhen benign (0.1); catalogued as COSV57699785; called by muse, mutect2, varscan2
- MFSD2B | c.456C>G p.F152L | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as COSV57855877, COSV57855935; called by muse, mutect2, varscan2
- MGA | c.2380G>T p.G794* | Nonsense Mutation (SNP) | VAF 3/10 reads (30%) | catalogued as COSV54960966; called by muse, mutect2
- MGAM | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.312); catalogued as COSV71884989; called by muse, mutect2, varscan2
- MGAT3 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV57867741; called by muse, mutect2, varscan2
- MGAT5B | c.854A>T p.Q285L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV56935030; called by muse, mutect2, varscan2
- MIA2 | c.490G>T p.E164* | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV54489385; called by muse, mutect2, varscan2
- MMP11 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.027); catalogued as rs374753818; called by muse, mutect2
- MMP16 | c.977C>G p.P326R | Missense Mutation (SNP) | VAF 88/178 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.359); catalogued as COSV99689063; called by muse, mutect2, varscan2
- MMP16 | c.976C>A p.P326T | Missense Mutation (SNP) | VAF 89/180 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99688250; called by muse, mutect2, varscan2
- MMP26 | c.481G>T p.G161C | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.041); catalogued as COSV56173404, COSV56173683; called by muse, mutect2, varscan2
- MMP27 | c.1464G>C p.K488N | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as COSV52779831, COSV52782270, COSV52782352; called by muse, mutect2, varscan2
- MMP27 | c.211G>T p.G71* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as COSV99498530; called by muse, mutect2
- MMP3 | c.1018G>T p.V340L | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV55407659; called by muse, mutect2, varscan2
- MMRN1 | c.3337A>G p.I1113V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs189291833, COSV53341477; called by muse, mutect2, varscan2
- MMRN2 | c.2473C>A p.P825T | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.409); catalogued as COSV64401223; called by muse, mutect2, varscan2
- MOG | c.394C>A p.H132N | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); catalogued as COSV65321643; called by muse, mutect2, varscan2
- MORC3 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV68687913, COSV68689057; called by muse, mutect2, varscan2
- MOXD1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.31); PolyPhen benign (0.045); catalogued as COSV60947804; called by muse, mutect2, varscan2
- MPO | c.1157C>G p.P386R | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs758609693, COSV56567667; called by muse, mutect2, varscan2
- MPP2 | c.827G>A p.R276H (on ENST00000461854 / NM_001278372.2; = p.R252H on NM_005374.5) | Missense Mutation (SNP) | VAF 58/127 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.505); catalogued as rs1006461685, COSV52239143; called by muse, mutect2, varscan2
- MRGPRF | c.20G>A p.W7* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV57996365; called by muse, varscan2
- MRGPRX4 | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58591527; called by muse, mutect2, varscan2
- MROH9 | c.1246G>T p.V416L | Missense Mutation (SNP) | VAF 52/89 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.64); catalogued as COSV63012868; called by muse, mutect2, varscan2
- MRPS24 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 8/79 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); catalogued as COSV58182097; called by muse, mutect2, varscan2
- MS4A3 | c.26C>G p.A9G | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.269); catalogued as COSV53937537; called by muse, mutect2, varscan2
- MSH5 | c.1052G>T p.R351L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100994916, COSV65211046; called by muse, mutect2, varscan2
- MSL3 | c.1420G>T p.E474* (on ENST00000312196 / NM_078629.4; = p.E308* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV56495337; called by muse, mutect2, varscan2
- MTCH1 | c.1022+1G>T p.X341_splice (on ENST00000373627 / NM_001271641.1; = p.X324_splice on NM_014341.2) | Splice Site (SNP) | VAF 42/143 reads (29%) | catalogued as COSV65321313; called by muse, mutect2, varscan2
- MTCL1 | c.3381G>T p.Q1127H (on ENST00000306329 / NM_001378206.1; = p.Q808H on NM_015210.4) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.135); catalogued as COSV60406403; called by muse, mutect2, varscan2
- MTF1 | c.506C>T p.T169I | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.86); catalogued as COSV65990227; called by muse, mutect2, varscan2
- MTSS1 | c.212G>T p.G71V | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61499365; called by muse, mutect2, varscan2
- MTUS2 | c.2242C>A p.P748T | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV70920255; called by muse, mutect2, varscan2
- MUC15 | c.871C>T p.P291S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV55556679; called by muse, mutect2
- MUC16 | c.41959G>T p.G13987C | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV66695686, COSV66697184; called by muse, mutect2, varscan2
- MUC16 | c.11221G>C p.G3741R | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.036); catalogued as COSV67485731; called by muse, mutect2, varscan2
- MXRA5 | c.4381G>C p.D1461H | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.07); PolyPhen benign (0.059); catalogued as COSV54238665, COSV54246155; called by muse, mutect2, varscan2
- MYCBP2 | c.2508A>T p.E836D (on ENST00000357337; = p.E874D on NM_015057.5) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.899); catalogued as COSV62034832; called by muse, mutect2, varscan2
- MYF5 | c.335C>A p.T112N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV57354600; called by muse, varscan2
- MYH10 | c.1385G>A p.G462E | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52608366; called by muse, mutect2, varscan2
- MYH13 | c.2433G>T p.R811S | Missense Mutation (SNP) | VAF 32/47 reads (68%) | SIFT deleterious (0.01); PolyPhen benign (0.221); catalogued as COSV52839312; called by muse, mutect2, varscan2
- MYH2 | c.4143C>A p.Y1381* | Nonsense Mutation (SNP) | VAF 23/303 reads (8%) | catalogued as COSV55446242; called by muse, mutect2
- MYH4 | c.2891C>T p.T964I | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV55124105; called by muse, mutect2, varscan2
- MYH7 | c.2625G>C p.E875D | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV62517757; called by muse, mutect2, varscan2
- MYH8 | c.3839G>T p.R1280I | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV67970726; called by muse, mutect2
- MYO10 | c.2794G>T p.E932* | Nonsense Mutation (SNP) | VAF 4/15 reads (27%) | catalogued as COSV57027944; called by muse, mutect2, varscan2
- MYO18B | c.6112C>A p.L2038M | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV59145116; called by muse, mutect2, varscan2
- MYO1G | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV51856528, COSV51857339; called by muse, mutect2, varscan2
- MYO3A | c.2115-1G>T p.X705_splice | Splice Site (SNP) | VAF 8/61 reads (13%) | catalogued as COSV56344342; called by muse, mutect2, varscan2
- MYO7A | c.6325A>T p.T2109S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV60021958; called by muse, mutect2, varscan2
- NAALADL2 | c.1355A>G p.H452R | Missense Mutation (SNP) | VAF 72/253 reads (28%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.998); catalogued as COSV69159433; called by muse, mutect2, varscan2
- NABP1 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs943122713, COSV57139320; called by muse, mutect2, varscan2
- NAIP | c.233C>A p.P78Q | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52002506; called by muse, mutect2, varscan2
- NAP1L1 | c.946G>T p.A316S | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV53876126; called by muse, mutect2, varscan2
- NAPSA | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.641); catalogued as COSV53798680; called by muse, mutect2, varscan2
- NAT16 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.882); catalogued as COSV55865477; called by muse, mutect2, varscan2
- NAV2 | c.5830-1G>T p.X1944_splice (on ENST00000396087 / NM_001244963.2; = p.X1885_splice on NM_145117.5) | Splice Site (SNP) | VAF 20/70 reads (29%) | catalogued as COSV60663890; called by muse, mutect2, varscan2
- NAV3 | c.1156G>T p.E386* | Nonsense Mutation (SNP) | VAF 7/49 reads (14%) | catalogued as COSV57072868, COSV57104963; called by muse, mutect2, varscan2
- NAV3 | c.1736G>T p.C579F | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV57104978; called by muse, mutect2, varscan2
- NBAS | c.918A>T p.L306F | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.034); catalogued as COSV55734051; called by muse, mutect2, varscan2
- NBPF25P | n.1443G>T | Splice Region (SNP) | VAF 106/316 reads (34%) | catalogued as rs1211189102; called by muse, mutect2, varscan2
- NCKAP1L | c.297G>T p.M99I | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV53211028; called by muse, mutect2, varscan2
- NCOA1 | c.2474C>T p.A825V | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV56048911; called by muse, mutect2, varscan2
- NDST4 | c.2423G>T p.C808F | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs550385229, COSV52132935; called by muse, mutect2, varscan2
- NDST4 | c.1760G>A p.R587K | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52132949; called by muse, mutect2, varscan2
- NEB | c.13489G>C p.E4497Q | Missense Mutation (SNP) | VAF 72/250 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV51449521; called by muse, mutect2, varscan2
- NEB | c.7869C>A p.D2623E | Missense Mutation (SNP) | VAF 66/317 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV51449554; called by muse, mutect2, varscan2
- NEO1 | c.1901G>A p.S634N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV56076839; called by muse, mutect2, varscan2
- NF1 | c.7444G>A p.D2482N (on ENST00000358273 / NM_001042492.3; = p.D2461N on NM_000267.3) | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.056); catalogued as COSV62216173; called by muse, mutect2, varscan2
- NFASC | c.965T>A p.M322K (on ENST00000339876 / NM_001378329.1; = p.M333K on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100364497; called by muse, mutect2, varscan2
- NFASC | c.966G>T p.M322I (on ENST00000339876 / NM_001378329.1; = p.M333I on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100364500; called by muse, mutect2, varscan2
- NGEF | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 12/69 reads (17%) | catalogued as COSV99889655; called by muse, mutect2, varscan2
- NGEF | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV99889674; called by muse, mutect2, varscan2
- NGEF | c.127C>G p.Q43E | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV50945451, COSV99891164; called by muse, mutect2, varscan2
- NID2 | c.2437G>T p.G813C | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53495088; called by muse, mutect2, varscan2
- NKX6-1 | c.698A>G p.D233G | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV55685611; called by muse, mutect2, varscan2
- NLGN1 | c.1438G>T p.G480C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV64343675; called by muse, mutect2, varscan2
- NLRC5 | c.4809G>T p.R1603S | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.102); catalogued as COSV52661222, COSV99348382; called by muse, mutect2, varscan2
- NLRP11 | c.1587G>A p.M529I | Missense Mutation (SNP) | VAF 85/148 reads (57%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV64088520; called by muse, mutect2, varscan2
- NLRP6 | c.1351G>C p.E451Q | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV56460561, COSV56461633; called by muse, mutect2, varscan2
- NLRP8 | c.2039C>A p.S680Y | Missense Mutation (SNP) | VAF 40/77 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as COSV52588905, COSV52592385; called by muse, mutect2, varscan2
- NME7 | c.265A>T p.S89C | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV63169798; called by muse, mutect2, varscan2
- NOBOX | c.767A>G p.Q256R | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV56196926; called by muse, mutect2, varscan2
- NOL11 | c.2123G>C p.R708T | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV53525146; called by muse, mutect2, varscan2
- NOTCH4 | c.2774G>T p.S925I | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV66683069; called by muse, mutect2, varscan2
- NOTCH4 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66683073; called by muse, mutect2, varscan2
- NPAP1 | c.392G>T p.R131L | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV100275650, COSV61510297; called by muse, mutect2
- NPAP1 | c.2486C>T p.P829L | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.778); catalogued as COSV61510303; called by muse, mutect2, varscan2
- NPHP3 | c.3439G>A p.E1147K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.935); catalogued as COSV58632652; called by muse, mutect2, varscan2
- NR1H3 | c.668A>T p.Q223L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV68008750; called by muse, mutect2, varscan2
- NRG1 | c.1126G>A p.V376I (on ENST00000405005 / NM_013964.5; = p.V381I on NM_013956.5) | Missense Mutation (SNP) | VAF 42/152 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs757580752, COSV55172230; called by muse, mutect2, varscan2
- NRP1 | c.1885A>T p.T629S | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.169); catalogued as COSV55175367; called by muse, mutect2, varscan2
- NRXN1 | c.1027G>T p.V343F | Missense Mutation (SNP) | VAF 39/123 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV100455672; called by muse, mutect2, varscan2
- NSRP1 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV55935006; called by muse, mutect2, varscan2
- NT5C1B | c.73_74insC p.E25Afs*7 | Frame Shift Ins (INS) | VAF 39/133 reads (29%) | catalogued as COSV100410129, COSV100410310; called by mutect2, pindel, varscan2
- NTF3 | c.686C>T p.S229L | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as COSV58418218; called by muse, mutect2, varscan2
- NUAK2 | c.1641C>A p.S547R | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65682427; called by muse, mutect2, varscan2
- NUDCD1 | c.391G>A p.D131N | Missense Mutation (SNP) | VAF 57/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs997534100, COSV53459771; called by muse, mutect2, varscan2
- NUP107 | c.449-2A>C p.X150_splice | Splice Site (SNP) | VAF 11/23 reads (48%) | catalogued as COSV99971854; called by mutect2, varscan2
- NUP43 | c.715G>C p.D239H | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV61190991; called by muse, mutect2, varscan2
- NUTM1 | c.1069C>A p.P357T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.823); catalogued as COSV59216670; called by muse, mutect2, varscan2
- OAF | c.546A>T p.Q182H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100202885, COSV61109782; called by muse, mutect2, varscan2
- OAS2 | c.2066G>T p.G689V | Missense Mutation (SNP) | VAF 90/284 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as COSV60804036; called by muse, mutect2, varscan2
- OCM2 | c.163C>T p.Q55* | Nonsense Mutation (SNP) | VAF 31/86 reads (36%) | catalogued as COSV57535828; called by muse, mutect2, varscan2
- OCM2 | c.23G>T p.S8I | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV57535160, COSV99990899; called by muse, mutect2, varscan2
- ODAPH | c.86C>A p.T29K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV61140864, COSV61141580; called by muse, mutect2, varscan2
- OLFML2B | c.1133C>G p.P378R | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV54199396, COSV54199471; called by muse, mutect2, varscan2
- OLR1 | c.382C>G p.L128V | Missense Mutation (SNP) | VAF 33/101 reads (33%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.643); catalogued as COSV58872503; called by muse, mutect2, varscan2
- OOSP2 | c.234C>G p.I78M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV53929880; called by muse, mutect2, varscan2
- OR10A2 | c.16C>A p.L6M | Missense Mutation (SNP) | VAF 34/210 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV56300196; called by muse, mutect2, varscan2
- OR10A4 | c.161C>A p.S54Y | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV65842362; called by muse, mutect2, varscan2
- OR10G8 | c.181C>T p.L61F | Missense Mutation (SNP) | VAF 20/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs571022074, COSV70908413, COSV70908571; called by muse, mutect2, varscan2
- OR10J5 | c.665C>A p.S222Y | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV58387400; called by muse, mutect2, varscan2
- OR10W1 | c.845C>A p.A282D | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs1176929613, COSV67720794; called by muse, mutect2, varscan2
- OR11H1 | c.751G>C p.V251L | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); catalogued as COSV99421867; called by muse, mutect2, varscan2
- OR13C8 | c.785C>A p.P262H | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58612128; called by muse, mutect2, varscan2
- OR13F1 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.033); catalogued as COSV58252435; called by muse, mutect2, varscan2
- OR2A2 | c.572C>T p.T191I | Missense Mutation (SNP) | VAF 62/203 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.654); catalogued as COSV68872367; called by muse, mutect2, varscan2
- OR2H1 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.998); catalogued as COSV65811262; called by muse, mutect2, varscan2
- OR2L3 | c.678C>A p.H226Q | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.014); catalogued as COSV63456033; called by muse, mutect2, varscan2
- OR2M2 | c.608G>T p.C203F | Missense Mutation (SNP) | VAF 185/310 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62899175; called by muse, mutect2, varscan2
- OR4A15 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.048); catalogued as COSV59033609; called by muse, mutect2, varscan2
- OR4C15 | c.104G>T p.C35F | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV58952645, COSV58954941; called by muse, mutect2, varscan2
- OR4K15 | c.668T>G p.I223R (on ENST00000305051; = p.I199R on NM_001005486.1) | Missense Mutation (SNP) | VAF 39/157 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV59302993; called by muse, mutect2, varscan2
- OR4M1 | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60063023, COSV60063140; called by muse, mutect2
- OR4N2 | c.284G>A p.R95K | Missense Mutation (SNP) | VAF 31/338 reads (9%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as COSV60051058, COSV60054174; called by muse, mutect2
- OR51B5 | c.612A>G p.I204M | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.017); catalogued as rs1478463510, COSV56175613; called by muse, mutect2, varscan2
- OR51Q1 | c.217C>A p.L73M | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as COSV56178825; called by muse, mutect2, varscan2
- OR52R1 | c.245C>A p.P82H | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61888509; called by muse, mutect2, varscan2
- OR56A1 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.057); catalogued as COSV57362062, COSV57363619; called by muse, mutect2, varscan2
- OR5AS1 | c.673G>T p.V225L | Missense Mutation (SNP) | VAF 43/122 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV57982904; called by muse, varscan2
- OR5D13 | c.17G>C p.R6T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV62333146, COSV62334912, COSV62335581; called by muse, mutect2, varscan2
- OR5K3 | c.928C>T p.H310Y | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV67349665, COSV67350528; called by muse, mutect2, varscan2
- OR5M3 | c.695G>T p.R232M | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56566878, COSV56567421; called by muse, mutect2, varscan2
- OR5T3 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 14/114 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as COSV57382116; called by muse, mutect2, varscan2
- OR6B1 | c.373G>T p.A125S | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV68770522; called by muse, mutect2, varscan2
- OR6K3 | c.767G>C p.C256S (on ENST00000368146; = p.C240S on NM_001005327.2) | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100933818, COSV63746290; called by muse, mutect2, varscan2
- OR7A5 | c.820G>T p.A274S | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV59235257; called by muse, mutect2, varscan2
- OR7D4 | c.286G>T p.G96W | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100432782, COSV58071367; called by muse, mutect2, varscan2
- OR8J1 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0.042); catalogued as COSV57319646; called by muse, mutect2, varscan2
- OR9A2 | c.52G>T p.G18W | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV63306724; called by muse, mutect2, varscan2
- OR9A4 | c.735C>A p.F245L | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV101516519, COSV71885913; called by muse, mutect2, varscan2
- PAK5 | c.954C>A p.Y318* | Nonsense Mutation (SNP) | VAF 72/160 reads (45%) | catalogued as COSV62035325; called by muse, mutect2, varscan2
- PAMR1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.765); catalogued as rs745624580, COSV53515602; called by muse, mutect2, varscan2
- PANK3 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53322978, COSV99496260; called by muse, mutect2, varscan2
- PAPLN | c.854A>G p.Q285R (on ENST00000554301; = p.Q258R on NM_173462.4) | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.294); catalogued as COSV53722172; called by muse, mutect2, varscan2
- PAPOLB | c.1649G>T p.S550I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV68202988; called by muse, mutect2, varscan2
- PARP14 | c.5086G>A p.G1696S | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71735403; called by muse, mutect2, varscan2
- PARP15 | c.1999C>G p.Q667E (on ENST00000464300 / NM_001113523.3; = p.Q433E on NM_152615.2) | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs911855571, COSV59974450; called by muse, mutect2, varscan2
- PASK | c.1668G>C p.E556D | Missense Mutation (SNP) | VAF 26/231 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.078); catalogued as COSV52149637, COSV52158556; called by muse, mutect2, varscan2
- PCDH15 | c.4882C>A p.P1628T (on ENST00000644397 / NM_001354429.2; = p.P1570T on NM_001142771.2) | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV64724931; called by muse, mutect2, varscan2
- PCDH17 | c.724G>C p.V242L | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV64976244, COSV64979907; called by muse, mutect2, varscan2
- PCDH17 | c.2340G>T p.M780I | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.017); catalogued as COSV64974822, COSV64977857; called by muse, mutect2, varscan2
- PCDH18 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 27/153 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as COSV61271390; called by muse, mutect2, varscan2
- PCDHA13 | c.828T>A p.D276E | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.031); catalogued as COSV56536393; called by muse, mutect2, varscan2
- PCDHA3 | c.288C>A p.C96* | Nonsense Mutation (SNP) | VAF 66/180 reads (37%) | catalogued as rs529252017, COSV65367602, COSV65370261; called by muse, mutect2, varscan2
- PCDHA9 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.975); catalogued as rs1364235763, COSV65325112; called by muse, mutect2, varscan2
- PCDHA9 | c.937A>T p.S313C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.07); catalogued as COSV65331446; called by muse, varscan2
- PCDHB16 | c.1764G>T p.K588N | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV53368983; called by muse, mutect2, varscan2
- PCDHB5 | c.2267G>C p.G756A | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.053); catalogued as COSV50664225; called by muse, mutect2, varscan2
- PCDHGA11 | c.2194G>C p.G732R | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.014); catalogued as COSV53912125, COSV54010412; called by muse, mutect2, varscan2
- PDCL2 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV55262274; called by muse, mutect2
- PDE1B | c.1181G>T p.R394L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.26); catalogued as rs143206355, COSV54490043, COSV99226542; called by muse, mutect2, varscan2
- PDE2A | c.2338C>A p.L780I | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.442); catalogued as COSV57812060; called by muse, mutect2, varscan2
- PDGFRA | c.3009G>T p.W1003C | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.43); catalogued as rs981559406, COSV57272140; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDILT | c.1303C>A p.Q435K | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as COSV56704393; called by muse, mutect2, varscan2
- PEG3 | c.2651G>T p.G884V | Missense Mutation (SNP) | VAF 40/67 reads (60%) | SIFT tolerated (0.26); PolyPhen benign (0.02); catalogued as COSV55636844, COSV55643964; called by muse, mutect2, varscan2
- PELP1 | c.1605G>T p.M535I | Missense Mutation (SNP) | VAF 60/97 reads (62%) | SIFT tolerated (0.36); PolyPhen benign (0.344); catalogued as rs1416998388, COSV52591158; called by muse, mutect2, varscan2
- PGC | c.603G>C p.Q201H | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); catalogued as COSV63123592; called by muse, mutect2, varscan2
- PGK2 | c.164C>A p.A55D | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59165222; called by muse, varscan2
- PHF20 | c.2230C>T p.Q744* | Nonsense Mutation (SNP) | VAF 17/79 reads (22%) | catalogued as COSV64977303; called by muse, mutect2, varscan2
- PIK3C2G | c.924T>A p.N308K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV56827347; called by muse, mutect2, varscan2
- PIK3R4 | c.4026G>T p.Q1342H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62034323; called by muse, mutect2, varscan2
- PIP5K1C | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.106); catalogued as COSV58955128; called by muse, mutect2, varscan2
- PIWIL2 | c.385G>T p.G129W | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV63253525; called by muse, mutect2, varscan2
- PKDREJ | c.6646G>A p.E2216K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV53548089; called by muse, mutect2, varscan2
- PKP4 | c.578G>C p.R193T | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67676994; called by muse, mutect2, varscan2
- PLB1 | c.2030G>T p.G677V | Missense Mutation (SNP) | VAF 39/122 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59833504; called by muse, mutect2, varscan2
- PLCB1 | c.638G>T p.R213I | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV62044325, COSV62063893; called by muse, mutect2, varscan2
- PLCE1 | c.5446T>A p.Y1816N | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53366551; called by muse, mutect2, varscan2
- PLEC | c.13397G>T p.R4466L (on ENST00000322810 / NM_201380.4; = p.R4356L on NM_000445.5) | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as rs372622946, COSV59680731; called by muse, mutect2, varscan2
- PLEKHH3 | c.1182G>C p.E394D | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1459166157, COSV52217179, COSV52219294; called by muse, mutect2, varscan2
- PLPPR4 | c.1274T>C p.V425A | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs370842121; called by muse, mutect2, varscan2
- PLXNA2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 44/84 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65443958; called by muse, mutect2, varscan2
- PNLIP | c.454C>A p.L152I | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100981791; called by muse, mutect2, varscan2
- POLE | c.5797A>G p.I1933V | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs758762868, COSV57687881; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLQ | c.4807C>G p.Q1603E | Missense Mutation (SNP) | VAF 64/267 reads (24%) | SIFT tolerated (0.7); PolyPhen benign (0.026); catalogued as COSV51759157; called by muse, mutect2, varscan2
- POR | c.365T>A p.L122Q | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV67518104; called by muse, mutect2, varscan2
- POTEE | c.2798G>T p.S933I | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV58228954, COSV58240867; called by muse, varscan2
- POU4F2 | c.791G>T p.R264L | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV55586319; called by mutect2, varscan2
- POU6F2 | c.793C>A p.P265T | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.025); catalogued as COSV68880411; called by muse, mutect2, varscan2
- PPP1R12A | c.926A>G p.D309G | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV54112584; called by muse, mutect2, varscan2
- PPP1R13L | c.2333C>G p.S778C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100714799; called by muse, mutect2, varscan2
- PPP1R15B | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 35/118 reads (30%) | catalogued as COSV65816377; called by muse, mutect2, varscan2
- PRDM1 | c.1475C>G p.P492R | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV64844487, COSV64846472; called by muse, mutect2, varscan2
- PRDM16 | c.1969G>T p.G657W | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV54604602; called by muse, mutect2, varscan2
- PRDM9 | c.1524C>A p.N508K | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV57011504; called by muse, mutect2, varscan2
- PRDX6 | c.486G>T p.R162S | Missense Mutation (SNP) | VAF 109/197 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61166119; called by muse, mutect2, varscan2
- PREX2 | c.2560G>T p.E854* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV55794407; called by muse, mutect2, varscan2
- PRKD1 | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs146285949; called by muse, mutect2, varscan2
- PRKDC | c.12108A>T p.K4036N | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.02); catalogued as COSV58060738; called by muse, mutect2, varscan2
- PRKG1 | c.2014G>T p.D672Y | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV64776115; called by muse, mutect2, varscan2
- PRKN | c.1057G>T p.E353* | Nonsense Mutation (SNP) | VAF 51/171 reads (30%) | catalogued as COSV58239542, COSV58258013; called by muse, mutect2, varscan2
- PSD2 | c.2014G>T p.A672S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV51207748; called by muse, mutect2, varscan2
- PSG11 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.067); catalogued as rs745836316, COSV60454820, COSV60457274; called by muse, varscan2
- PSG4 | c.208G>T p.G70W | Missense Mutation (SNP) | VAF 120/247 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54939481; called by muse, mutect2, varscan2
- PSMA6 | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV54838238, COSV54838856; called by muse, mutect2, varscan2
- PSMD2 | c.2384G>A p.G795E | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59531086; called by muse, mutect2, varscan2
- PTGDR | c.131C>A p.S44* | Nonsense Mutation (SNP) | VAF 6/20 reads (30%) | catalogued as COSV60094810; called by mutect2, varscan2
- PTGIR | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.017); catalogued as COSV52191460, COSV52191940; called by muse, mutect2
- PTPN18 | c.448G>C p.E150Q | Missense Mutation (SNP) | VAF 54/276 reads (20%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.453); catalogued as COSV51560362; called by muse, mutect2, varscan2
- PTPN5 | c.1207G>T p.E403* | Nonsense Mutation (SNP) | VAF 38/118 reads (32%) | catalogued as COSV100659668, COSV62124493; called by muse, varscan2
- PTPRB | c.89C>A p.T30N | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.003); catalogued as COSV54250368; called by muse, mutect2, varscan2
- PTPRE | c.224G>T p.R75M | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV54557156; called by muse, mutect2, varscan2
- PTPRG | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs1362184918, COSV55658321; called by muse, mutect2, varscan2
- PTPRG | c.3868G>A p.E1290K | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as COSV55637194; called by muse, mutect2, varscan2
- PTPRH | c.3333C>A p.H1111Q | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT tolerated (0.45); PolyPhen benign (0.079); catalogued as COSV54748835; called by muse, mutect2, varscan2
- PTPRN | c.649del p.R217Vfs*101 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as COSV55346441; called by mutect2, pindel, varscan2
- PTPRZ1 | c.1806C>A p.N602K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.084); catalogued as COSV101100366; called by muse, mutect2, varscan2
- PTPRZ1 | c.3029C>A p.T1010K | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.327); catalogued as rs775565817, COSV66443684; called by muse, mutect2, varscan2
- PXDNL | c.4352G>C p.R1451T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV62496167; called by muse, mutect2
- PZP | c.3109C>T p.R1037* | Nonsense Mutation (SNP) | VAF 51/146 reads (35%) | catalogued as rs779390341, COSV54368176; called by muse, mutect2, varscan2
- R3HDM1 | c.2296A>T p.T766S | Missense Mutation (SNP) | VAF 54/122 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV51531012; called by muse, mutect2, varscan2
- RAB3GAP2 | c.703G>T p.V235L | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.31); PolyPhen benign (0.163); catalogued as COSV52966868, COSV52966988; called by muse, mutect2, varscan2
- RAC2 | c.566G>C p.C189S | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.385); catalogued as COSV50775163; called by muse, mutect2, varscan2
- RAG1 | c.107G>T p.R36I | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as COSV55027525, COSV55027831; called by muse, mutect2, varscan2
- RALGAPB | c.1276A>G p.S426G | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV53442721; called by muse, mutect2, varscan2
- RAMP2 | c.170C>A p.T57K | Missense Mutation (SNP) | VAF 96/242 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369493002, COSV53823483; called by muse, mutect2, varscan2
- RAPGEF4 | c.1469G>C p.G490A | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV51381934, COSV51409460; called by muse, mutect2, varscan2
- RELN | c.9603T>C p.S3201= | Splice Region (SNP) | VAF 41/130 reads (32%) | catalogued as COSV59027774; called by muse, mutect2, varscan2
- RELN | c.3228G>C p.Q1076H | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.174); catalogued as rs930729213, COSV59027782; called by muse, mutect2, varscan2
- RENBP | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV64170458; called by muse, mutect2, varscan2
- RFFL | c.293G>T p.R98L | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52073692; called by muse, mutect2, varscan2
- RFPL3 | c.517C>A p.P173T (on ENST00000249007 / NM_001098535.1; = p.P144T on NM_006604.2) | Missense Mutation (SNP) | VAF 42/131 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.278); catalogued as COSV50752046; called by muse, mutect2, varscan2
- RFX6 | c.898G>T p.D300Y | Missense Mutation (SNP) | VAF 43/151 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV60588090, COSV60588166; called by muse, mutect2, varscan2
- RHPN1 | c.1695G>T p.W565C | Missense Mutation (SNP) | VAF 31/65 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56648801; called by muse, mutect2, varscan2
- RNASE12 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 23/77 reads (30%) | catalogued as COSV60088079; called by muse, mutect2, varscan2
- RNF122 | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); catalogued as rs1402439692, COSV56359888; called by muse, mutect2, varscan2
- RNF150 | c.908C>A p.S303Y | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.492); catalogued as COSV100153999, COSV60797639; called by muse, mutect2, varscan2
- RNF17 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV55048480; called by muse, mutect2, varscan2
- RNF17 | c.2983-1G>T p.X995_splice | Splice Site (SNP) | VAF 12/50 reads (24%) | catalogued as COSV55048487; called by muse, mutect2, varscan2
- RNF175 | c.426G>C p.L142F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as COSV56843237; called by muse, mutect2, varscan2
- RNF31 | c.1378G>T p.G460W | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.299); catalogued as COSV53760879, COSV99396346; called by muse, mutect2, varscan2
- RP1L1 | c.5204G>T p.S1735I | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV66758962; called by muse, mutect2, varscan2
- RP1L1 | c.2299G>T p.G767W | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV101223369; called by muse, mutect2, varscan2
- RP9 | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51807496; called by muse, mutect2, varscan2
- RPA2 | c.409-2A>T p.X137_splice | Splice Site (SNP) | VAF 4/20 reads (20%) | catalogued as COSV57878577; called by muse, mutect2, varscan2
- RPL3L | c.964C>A p.H322N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.399); catalogued as rs143428526, COSV51908078; called by muse, mutect2, varscan2
- RTEL1 | c.2403G>C p.Q801H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs1219370345, COSV58899769; called by muse, mutect2, varscan2
- RTP2 | c.151C>A p.H51N | Missense Mutation (SNP) | VAF 30/124 reads (24%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.983); catalogued as COSV64079358; called by muse, mutect2, varscan2
- RUBCNL | c.274C>T p.P92S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV59792947; called by muse, mutect2, varscan2
- RUNDC3B | c.872G>C p.R291P | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV100406878, COSV56694591, COSV56696158; called by muse, varscan2
- RWDD4 | c.505G>T p.G169C | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58394412; called by muse, mutect2, varscan2
- RYR1 | c.4478T>A p.M1493K | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV62107306; called by muse, mutect2, varscan2
- RYR3 | c.4368G>T p.L1456F | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV66804824; called by muse, mutect2, varscan2
- SACS | c.4388G>T p.R1463I | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1208745761, COSV66545558; called by muse, mutect2, varscan2
- SACS | c.3239C>A p.S1080* | Nonsense Mutation (SNP) | VAF 30/130 reads (23%) | catalogued as COSV66545563; called by muse, mutect2, varscan2
- SARDH | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 22/64 reads (34%) | catalogued as COSV53835363; called by muse, mutect2, varscan2
- SCN3B | c.567G>T p.E189D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.952); catalogued as COSV54800837; called by muse, mutect2, varscan2
- SCUBE1 | c.397G>T p.V133F | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.943); catalogued as COSV51815499; called by muse, mutect2, varscan2
- SDK1 | c.6187G>T p.A2063S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV67384333; called by muse, mutect2, varscan2
- SDK2 | c.3915G>T p.M1305I | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV66193937; called by muse, mutect2
- SDK2 | c.3721G>T p.E1241* | Nonsense Mutation (SNP) | VAF 23/49 reads (47%) | catalogued as COSV66193946; called by muse, mutect2, varscan2
- SEC23IP | c.1338G>T p.L446F | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64832735; called by muse, varscan2
- SECISBP2L | c.2885G>T p.G962V (on ENST00000559471 / NM_001193489.2; = p.G917V on NM_014701.4) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55937001; called by muse, mutect2, varscan2
- SEL1L3 | c.934G>C p.D312H | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53547825; called by muse, mutect2
- SEPTIN14 | c.912C>A p.H304Q | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV66430241; called by muse, mutect2, varscan2
- SERPINA7 | c.445G>C p.D149H | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs1298036379, COSV59666552, COSV59667010; called by muse, mutect2, varscan2
- SERPINE2 | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.877); catalogued as rs11548971, COSV51459507; called by muse, mutect2, varscan2
- SERPINI2 | c.1097T>C p.I366T | Missense Mutation (SNP) | VAF 31/129 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as rs746419909, COSV52988332; called by muse, mutect2, varscan2
- SETBP1 | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 29/74 reads (39%) | catalogued as COSV56333282; called by muse, mutect2, varscan2
- SEZ6L | c.1358G>A p.G453E | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50657791; called by muse, mutect2, varscan2
- SFSWAP | c.2186C>T p.P729L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.01); catalogued as COSV55524815, COSV55526040; called by mutect2, varscan2
- SGIP1 | c.205G>T p.A69S | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV52776690, COSV52778706; called by muse, mutect2, varscan2
- SGO2 | c.3277C>G p.H1093D | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.086); catalogued as COSV63417238; called by muse, mutect2, varscan2
- SI | c.599G>T p.S200I | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52295569; called by muse, mutect2, varscan2
- SIGLEC1 | c.4357C>A p.L1453M | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV99167482; called by muse, varscan2
- SIGLEC12 | c.1469T>A p.L490Q (on ENST00000291707 / NM_053003.4; = p.L372Q on NM_033329.2) | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as COSV52464191; called by muse, mutect2, varscan2
- SIGLEC5 | c.1229G>T p.C410F | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55782772, COSV99707707; called by muse, mutect2, varscan2
- SIRPB2 | c.858A>T p.T286= | Splice Region (SNP) | VAF 53/121 reads (44%) | catalogued as COSV63123612; called by muse, mutect2, varscan2
- SLAIN1 | c.1601C>G p.P534R (on ENST00000466548; = p.P271R on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV57388621; called by muse, mutect2
- SLAMF6 | c.521C>T p.S174L | Missense Mutation (SNP) | VAF 40/120 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV63587947; called by muse, mutect2, varscan2
- SLC12A5 | c.1514C>A p.P505Q (on ENST00000454036 / NM_001134771.2; = p.P482Q on NM_020708.5) | Missense Mutation (SNP) | VAF 79/237 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54799898; called by muse, mutect2, varscan2
- SLC13A5 | c.134T>A p.M45K | Missense Mutation (SNP) | VAF 49/82 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53424637; called by muse, mutect2, varscan2
- SLC16A12 | c.142G>T p.G48C | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57948658, COSV57953479; called by muse, mutect2, varscan2
- SLC17A5 | c.906C>A p.N302K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63288180; called by mutect2, varscan2
- SLC17A9 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV64848067; called by muse, mutect2, varscan2
- SLC25A13 | c.1381G>C p.E461Q | Missense Mutation (SNP) | VAF 84/245 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55712199; called by muse, mutect2, varscan2
- SLC2A3 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1207803145, COSV50006205; called by muse, mutect2, varscan2
- SLC35F6 | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60427014; called by muse, mutect2, varscan2
- SLC36A3 | c.5C>A p.S2* | Nonsense Mutation (SNP) | VAF 40/80 reads (50%) | catalogued as COSV58857984; called by muse, mutect2, varscan2
- SLC5A10 | c.1259T>A p.L420H (on ENST00000395645 / NM_001042450.4; = p.L436H on NM_152351.5) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99408226; called by muse, mutect2, varscan2
- SLC6A9 | c.288G>C p.Q96H (on ENST00000360584 / NM_201649.4; = p.Q42H on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62211856; called by muse, mutect2, varscan2
513 further variants in this file (224 protein-altering or splice-affecting, 257 silent, 32 other) are not listed here.
